Gene-level copy-number profile of tumor specimen ALCH-B1UY-TTP1-A from ALCHEMIST case ALCH-B1UY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,781 days).
Specimen ALCH-B1UY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82b6e368-a45f-40cf-a596-0e473bf9cbde.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/7f0e0afe-ae89-4709-9134-68b0cd7592ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 10,914; copy number 2: 41,797; copy number 3: 3,654; copy number 4: 2,526; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,369,110–27,395,814, 4 genes: FCN3, CD164L2, FO393419.1, GPR3.
- chr17:50,464,496–50,468,906, 1 gene (within-gene range 0–2): CHAD.
- chr18:76,385,642–76,389,406, 1 gene (within-gene range 0–2): AC009716.2.
- chr19:19,254,748–19,273,391, 4 genes: AC138430.1, HAPLN4, AC138430.2, TM6SF2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,280,436–1,292,029, 1 gene, copy number 9: SCNN1D.

Autosomal genes at a single copy (total copy number 1): 8,073. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
